Surgical pathology report (de-identified scan), TCGA case TCGA-W2-A7HC, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Medical College of Wisconsin, specimen TCGA-W2-A7HC-01A (Primary Tumor).

[page 1 of 2]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Final result

Entered by

Component Results

SURG PATH FINAL REPORT:

Accession #:

Specimen:

Date of Procedure:

Performing Clinician:

A. Right adrenal

Clinical Notes:

A) Fresh tissue saved for
diagnosis: Pheochromocytoma.

tissue bank. Pre-op

Diagnosis:

A. Right adrenal, adrenalectomy:
- Pheochromocytoma.

Note: microscopic foci of vascular invasion and a focus of vascular invasion are noted. The biologic behavior of pheochromocytoma can be difficult to predict from the histology. The presence of foci of vascular invasion are worrisome; close clinical follow-up is therefore recommended.

(Electronically signed by)
Verified:

Gross:

A. The specimen is labeled "right adrenal." Received in and transferred to formalin is a 97 gram, 9.5 x 8.0 x 4.0 cm, portion of yellow-tan adipose tissue which contains an intact adrenal gland. The specimen is marked with black ink and serially sectioned to reveal a 6.0 x 5.3 x 4.3 cm soft, mottled, red-purple to brown mass. The mass is present within the medulla of the adrenal gland. The adrenal gland is 9.0 x 4.5 x 3.6 cm and exhibits a bright orange cortex. One end of the specimen exhibits a grossly uninvolved portion of adrenal with a central red-gray medulla. The mass appears surrounded by the adrenal cortex, which focally abuts the black inked surface of the specimen.

ICD-0-3
Pheochromocytoma NOS 8500/0
Site Adrenal gland NOS
C74.9
JH 9/4/13

[page 2 of 2]
[REDACTED]

A portion of fresh tissue is taken for tissue bank. Representative sections are submitted in cassettes A1 through A8.

Accession #:

Microscopic:
A histological examination has been performed.

Administrative Notes:

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time

Lab Status
In process

Entered by

Criteria *W 8/29/13* No

Source: NCI Genomic Data Commons file 5437dcef-073a-4ce1-bab0-beb830686cd3 (TCGA-W2-A7HC.ADF63DF6-EA2C-4B38-B7D7-5CC12C6DEFF1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).